MMRF case MMRF_2407 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a8a046c7-0704-4afd-bbde-2a4223d30aad

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 46.0 years (16,789 days); ISS stage: I; Days to last known disease status: 792 days (2.2 years); Days to last follow up: 792 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 33 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 8 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 36 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 64 days; Days to treatment end: 64 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 89 days; Days to treatment end: 89 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 90 days; Days to treatment end: 90 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 207 days; Days to treatment end: 210 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 209 days; Days to treatment end: 209 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 211 days; Days to treatment end: 211 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 167 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.105 mg/dL; Immunoglobulin G 6.49 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.05 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.55 mmol/L; Albumin 48 g/L; Total Protein 6.9 g/dL; Glucose 5.78 mmol/L.
- Day 95 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.141 mg/dL; Immunoglobulin G 7.07 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 1.62 µg/mL; Lactate Dehydrogenase 8.07 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 1.6 ×10⁹/L; Absolute Neutrophil 1.57 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.03 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 12.8 mmol/L.
- Day 173 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.438 mg/dL; Immunoglobulin G 7.79 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.15 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 11.1 mmol/L.
- Day 274 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.549 mg/dL; Immunoglobulin G 8.17 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 6.77 mmol/L.
- Day 393 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.712 mg/dL; Immunoglobulin G 7.91 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 1.07 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 8.69 mmol/L.
- Day 491 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.722 mg/dL; Immunoglobulin G 8.38 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.23 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 6.77 mmol/L.
- Day 585 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.658 mg/dL; Immunoglobulin G 8.3 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 7.26 mmol/L.
- Day 701 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.683 mg/dL; Immunoglobulin G 8.89 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 7.98 mmol/L.
- Day 792 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.671 mg/dL; Immunoglobulin G 8.06 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 7.26 mmol/L.

Other clinical attributes
- Day -9: Weight: 105 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2407_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_2407_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
